Surgical pathology report (de-identified scan), TCGA case TCGA-B8-A54K, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-A54K-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Carcinoma, renal cell NOS
Clear cell type 8312/3
Site: (R) Kidney NOS
C64.9
11/30/12 JN

Diagnosis:

A: Kidney, right, partial nephrectomy

Tumor histologic type/subtype: renal cell carcinoma, clear cell type

Sarcomatoid features: not identified

Histologic grade (if applicable): 1 (of 4, Fuhrman classification)

Tumor size (greatest dimension): 2.5 cm

Tumor focality: unifocal

Extent of tumor invasion:

Extra-capsular invasion into perirenal adipose tissue: not identified

Venous: not identified

Lymphatic: not identified

Surgical margins:

Parenchymal margin: negative

Perinephric soft tissue margin: negative

Adrenal gland: n/a

Lymph nodes: n/a

AJCC Stage: pT1a pNx pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Perirenal adipose tissue, removal
- Fat, no carcinoma identified

[page 2 of 3]
Clinical History:

The patient is a -year-old male with a renal mass.

Gross Description:

Specimen A:

Specimen fixation: Formalin

Type of specimen: Partial nephrectomy

Side of specimen: Right

Size and weight of specimen: 8.5 grams, and 3 x 2.5 x 2.0 cm

Orientation: The deep margin is inked black and the renal capsule is inked blue.

Presence/absence of adrenal gland: Absent

Tumor site: Lower pole

Tumor description: Heterogeneous solid red/tan multicystic mass.
The tumor is well-circumscribed.

Tumor size: 2.0 x 1.5 x 2.5 cm

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: Confined

Extent of invasion:

Perirenal adipose tissue: None available for comment.

Gerota' s fascia: Not available for observation

Renal vein: Not available for observation

Ureter: Not available for observation

Renal Sinus: Not available for observation

Pelvicaliceal: Not available for observation

Adrenal: Not available for observation

Other organs: N/A

[page 3 of 3]
Surgical margins:

Perirenal adipose tissue: Not available for observation

Renal vein: Not available for observation

Renal artery: Not available for observation

Ureter: Not available for observation

Description of kidney away from tumor: Pale tan, firm unremarkable renal parenchyma

Hilar lymph nodes: Not available for observation

Other significant findings: None

Tissue submitted for special investigations: Tumor is submitted to tissue procurement foundation.

Digital picture: None taken

Block Summary:

A1-A3 - Representative sections

Tissue remains in container.

Specimen B is additionally labeled "fat overlying tumor" and holds a fragment of yellow adipose tissue measuring 5.5 x 5.1 x 2.8 cm. The specimen is serially sectioned to reveal unremarkable lobulated yellow adipose tissue. No masses are identified. Representative sections are submitted in blocks B1-B3. Tissue remains in container.

Light Microscopy:

Light microscopic examination is performed by Dr. Sections of the renal mass show a clear cell neoplasm with focal papillary architecture, without psammoma bodies to suggest Xp11 translocation carcinoma. Features are interpreted as clear cell carcinoma. Dr. concurs.

Prn 1266/interim Z 90 days from TCOR specimen procurement, per TSS.

IFAA Discrepancy		X
Reviewed:	11/20/12	

Source: NCI Genomic Data Commons file c8e4e0d6-f0cc-4376-b62c-a39e8dd0dd4d (TCGA-B8-A54K.5B9CE117-C196-4704-AE0F-8B15EB54AFFE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).